Somatic mutation profile of tumor specimen MP2PRT-PAURMT-TMP1-A (aliquot MP2PRT-PAURMT-TMP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAURMT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.0 years (3,284 days).
Specimen MP2PRT-PAURMT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 87974237-9a54-4b67-9e60-8f775d2ac453.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAURMT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAURMT-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ab02972-1b62-4436-83c9-e9f79aa9aa8c

The open-access MAF lists 14 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 12, Silent 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS8 | c.2323C>T p.R775C | Missense Mutation (SNP) | VAF 157/427 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763877653, COSV99960186; called by muse, mutect2, varscan2
- B3GNT9 | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 34/650 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.123); catalogued as rs961063764; called by muse, mutect2
- IPO13 | c.2797G>A p.E933K | Missense Mutation (SNP) | VAF 137/311 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as rs1198835456, COSV54838327; called by muse, mutect2, varscan2
- KCNK2 | c.191C>T p.T64M (on ENST00000444842 / NM_001017425.3; = p.T49M on NM_014217.4) | Missense Mutation (SNP) | VAF 60/362 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); catalogued as rs1020025325, COSV67204439; called by muse, mutect2, varscan2
- MYOCD | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 26/258 reads (10%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs78520788; called by muse, mutect2, varscan2
- NAV1 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 257/818 reads (31%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.605); catalogued as rs1194516495; called by muse, mutect2, varscan2
- OR52K2 | c.898C>A p.Q300K | Missense Mutation (SNP) | VAF 67/234 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.966); catalogued as rs371023230; called by muse, mutect2, varscan2
- PLEKHA6 | c.2488C>T p.R830W | Missense Mutation (SNP) | VAF 266/817 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs759409183, COSV55332446; called by muse, mutect2, varscan2
- PREP | c.1697C>A p.S566Y (on ENST00000369110; = p.S632Y on NM_002726.5) | Missense Mutation (SNP) | VAF 17/459 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV64871074; called by muse, mutect2
- TNN | c.687C>A p.S229R | Missense Mutation (SNP) | VAF 253/749 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV53429596; called by muse, mutect2, varscan2
- CGN | c.816G>T p.W272C | Missense Mutation (SNP) | VAF 154/325 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNOT1 | c.4434+5G>A | Splice Region (SNP) | VAF 109/309 reads (35%) | called by muse, mutect2, varscan2
- MAMDC2 | c.367G>C p.D123H | Missense Mutation (SNP) | VAF 13/413 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- BMPER | c.759C>T p.Y253= | Silent (SNP) | VAF 64/209 reads (31%) | catalogued as rs377437543; called by muse, mutect2, varscan2
